Gene-level copy-number profile of tumor specimen ALCH-B2BN-TTP1-A from ALCHEMIST case ALCH-B2BN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.1 years (20,112 days).
Specimen ALCH-B2BN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ec0eab3a-a528-48d5-b51d-babe363a85cd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2BN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/6eaa69d1-03ed-4ac4-a739-873dffcc2765

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 164; copy number 1: 196; copy number 2: 3,187; copy number 3: 4,684; copy number 4: 35,423; copy number 5: 3,932; copy number 6: 9,960; copy number 7: 680; copy number 8: 66; copy number 9: 85; copy number 10: 7; copy number 12: 7.

Homozygous deletions (total copy number 0; autosomes only): 164 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,804,846–40,805,141, 1 gene (within-gene range 0–2): RN7SL326P.
- chr1:143,419,625–143,500,512, 7 genes: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr1:143,720,510–143,729,570, 2 genes: RNVU1-23, RNVU1-18.
- chr3:44,421,127–44,439,946, 1 gene (within-gene range 0–4): C3orf86.
- chr9:8,936,079–8,963,077, 1 gene (within-gene range 0–2): AL596451.1.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–2): RN7SL5P.
- chr9:61,581,813–64,889,063, 87 genes (broad region; genes not listed).
- chr12:50,057,548–50,167,533, 6 genes: ASIC1, SMARCD1, GPD1, COX14, AC074032.1, CERS5.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:33,875,039–33,950,420, 5 genes: AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16.
- chr16:56,351,886–56,353,524, 1 gene (within-gene range 0–4): AC009102.2.
- chr16:69,950,705–69,975,344, 2 genes: CLEC18A, AC026468.1.
- chr20:31,580,890–31,581,214, 2 genes: AL110115.2, RNU6-384P.
- chr21:7,744,962–9,368,775, 44 genes (within-gene range 0–3): SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 99 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,269,491–38,311,808, 7 genes, copy number 12 (within-gene range 6–12): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:76,048,051–76,132,187, 6 genes, copy number 9: MDH2, AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1.
- chr7:142,384,329–142,813,399, 72 genes, copy number 9 (broad region; genes not listed).
- chr7:155,611,231–155,645,205, 1 gene, copy number 10 (within-gene range 6–10): AC009403.1.
- chr11:118,193,725–118,316,175, 6 genes, copy number 10: JAML, HSPE1P18, MPZL3, MPZL2, AP002800.1, CD3E.
- chr11:120,325,296–120,489,937, 3 genes, copy number 9: TLCD5, ARHGEF12, 7SK.
- chr16:1,826,941–1,884,294, 4 genes, copy number 9 (within-gene range 4–9): FAHD1, MEIOB, AL031722.1, LINC00254.

Autosomal genes at a single copy (total copy number 1): 196. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
